Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5096, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5096-01A (Primary Tumor).

FINAL DIAGNOSIS

- PART 1: LEFT KIDNEY AND ADRENAL GLAND, NEPHRECTOMY AND
EXCISION -
- A. RENAL CELL CARCINOMA, CLEAR CELL VARIANT OF THE
LOWER POLE OF THE KIDNEY WITH FOCAL MICROSCOPIC
INVASION OF THE PERIPELVIC FAT.
- B. VASCULAR AND LYMPHATIC INVASION IDENTIFIED.
- C. RENAL VEIN MARGINS FREE OF TUMOR.
- D. ADRENAL GLAND FREE OF TUMOR.
- E. STAGE T3N1MX.
- PART 2: INFERIOR AORTIC NODE, EXCISION -
NO TUMOR SEEN.
- PART 3: NODAL MASS, EXCISION -
LYMPH NODE WITH METASTATIC RENAL CELL CARCINOMA.

Source: NCI Genomic Data Commons file 885d4747-4868-4e71-8360-fedf7ded99ae (TCGA-B0-5096.67853303-BD4C-4835-B30C-B0A76F9F86FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).